Gene-level copy-number profile of tumor specimen ALCH-B3IC-TTP1-A from ALCHEMIST case ALCH-B3IC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,937 days).
Specimen ALCH-B3IC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 48fc01fb-443f-4bdc-8b3d-a9278a603efb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3IC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/57202c8f-3c58-4540-8e64-e13b057d351e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 3,514; copy number 2: 53,834; copy number 3: 929; copy number 4: 68; copy number 5: 12; copy number 6: 2; copy number 7: 1; copy number 9: 4; copy number 14: 2; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,878,835–8,879,894, 1 gene (within-gene range 0–2): ENO1-AS1.
- chr3:75,328,549–75,371,342, 4 genes: MYLKP1, OR7E66P, OR7E22P, OR7E55P.
- chr3:138,947,217–138,953,990, 1 gene: FOXL2NB.
- chr5:134,005,147–134,005,562, 1 gene: AC008608.2.
- chr7:66,809,993–66,844,882, 1 gene (within-gene range 0–2): GTF2IRD1P1.
- chr9:6,639,139–6,639,604, 1 gene (within-gene range 0–2): RPL23AP57.
- chr11:70,603,304–70,604,859, 1 gene (within-gene range 0–2): AP001271.2.
- chr14:101,948,347–101,953,063, 2 genes: AL118558.3, AL118558.4.
- chr19:33,795,933–33,815,763, 1 gene: KCTD15.
- chr20:56,688,401–56,701,514, 2 genes: RN7SL170P, PTMAP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,772,749–3,775,982, 1 gene, copy number 5: SMIM1.
- chr11:1,012,823–1,249,676, 5 genes, copy number 5–6: MUC6, LINC02688, MUC2, MUC5AC, MUC5B-AS1.
- chr14:105,620,506–105,626,066, 1 gene, copy number 17 (within-gene range 3–17): IGHG4.
- chr14:105,647,924–105,649,057, 1 gene, copy number 6: COPDA1.
- chr16:1,221,651–1,263,845, 7 genes, copy number 5 (within-gene range 4–5): TPSG1, AC120498.10, TPSB2, TPSAB1, TPSD1, AC120498.2, PRSS29P.
- chr16:1,770,286–1,794,971, 6 genes, copy number 9–14 (within-gene range 2–14): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.
- chr16:88,382,959–88,440,757, 1 gene, copy number 7: ZNF469.

Autosomal genes at a single copy (total copy number 1): 3,338. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
